Somatic mutation profile of tumor specimen 0DF6VH from CCDI case PBBRVH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.0 years (5,116 days).
Specimen 0DF6VH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2330e8d9-e563-4426-b396-6db9fb9c72fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DF6VB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1fe3a009-c298-415f-b820-51cdcf970fb8

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Frame Shift Del 2, Silent 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 115/365 reads (32%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SMARCA4 | c.3727C>T p.R1243W | Missense Mutation (SNP) | VAF 85/487 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60786131, COSV60797427; called by muse, mutect2, varscan2
- TP53 | c.844C>G p.R282G | Missense Mutation (SNP) | VAF 410/624 reads (66%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.801); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- LTF | c.1201G>A p.A401T | Missense Mutation (SNP) | VAF 125/385 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.1); catalogued as rs1393094222, COSV51606623; called by muse, mutect2, varscan2
- RHOXF1 | c.175G>A p.G59S | Missense Mutation (SNP) | VAF 71/529 reads (13%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs782032966; called by muse, mutect2, varscan2
- ATRX | c.350del p.T117Ifs*10 | Frame Shift Del (DEL) | VAF 72/688 reads (10%) | called by mutect2, varscan2
- CCDC22 | c.883C>A p.H295N | Missense Mutation (SNP) | VAF 14/388 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- DACH2 | c.1316C>G p.P439R | Missense Mutation (SNP) | VAF 232/767 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- GPM6B | c.755T>G p.V252G | Missense Mutation (SNP) | VAF 69/736 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.44); called by muse, mutect2
- THBS2 | c.674del p.G225Vfs*63 | Frame Shift Del (DEL) | VAF 276/814 reads (34%) | called by mutect2, varscan2
- WDR33 | c.1247A>G p.N416S | Missense Mutation (SNP) | VAF 91/786 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- FASN | c.7035G>C p.L2345= | Silent (SNP) | VAF 59/414 reads (14%) | called by muse, mutect2, varscan2
- SHROOM4 | c.1338T>C p.T446= | Silent (SNP) | VAF 50/622 reads (8%) | called by muse, mutect2
- TMCO6 | c.*21C>A | 3'UTR (SNP) | VAF 9/192 reads (5%) | called by muse, mutect2
